MMRF case MMRF_2344 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/55f82b91-02d2-488f-a054-d3a255820ed7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,384 days); ISS stage: I; Days to last known disease status: 818 days (2.2 years); Days to last follow up: 818 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 267 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 219 days; Days to treatment end: 328 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 279 days; Days to treatment end: 328 days.
   Treatment given: Therapeutic agents: Daratumumab + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 338 days; Days to treatment end: 568 days (1.6 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 572 days (1.6 years); Days to treatment end: 572 days (1.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 573 days (1.6 years); Days to treatment end: 573 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 3.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 3.81 g/L; Immunoglobulin A 41.8 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.22 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 9.1 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.18 mg/dL.
- Day 90 (ECOG 0): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 3.07 g/L; Immunoglobulin A 29.1 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 12.8 ×10⁹/L; Absolute Neutrophil 9.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 6.44 mmol/L.
- Day 216 (ECOG 1): M Protein 1.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.998 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.555 mg/dL; Immunoglobulin G 2.76 g/L; Immunoglobulin A 22.7 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 279 (ECOG 1): M Protein 2.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.693 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.092 mg/dL; Immunoglobulin G 2.75 g/L; Immunoglobulin A 25.7 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 137 ×10⁹/L.
- Day 383 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.836 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.127 mg/dL; Immunoglobulin G 2.87 g/L; Immunoglobulin A 17.5 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 426 (ECOG 1): M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.539 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.583 mg/dL; Immunoglobulin G 4.08 g/L; Immunoglobulin A 9.34 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 322 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 511 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.521 mg/dL; Immunoglobulin G 8.39 g/L; Immunoglobulin A 4.08 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 5.8 g/dL; Glucose 5.89 mmol/L.
- Day 601 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.487 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.125 mg/dL; Immunoglobulin G 4.47 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 8.27 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.42 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 27 g/L; Total Protein 4.5 g/dL; Glucose 5.72 mmol/L.
- Day 742 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.611 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.631 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 6.05 mmol/L.
- Day 818 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.832 mg/dL; Immunoglobulin G 9.36 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.88 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -8: Weight: 120 kg; Height: 193 cm.

Biospecimens (3 samples)
- Sample MMRF_2344_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2344_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
- Sample MMRF_2344_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 383 days (1.0 years).
